Somatic mutation profile of tumor specimen ASCProject_0097_T3_WES (aliquot ASCProject_0097_T3_WES_1) from CMI case ASCProject_0097, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 38.5 years (14,044 days).
Specimen ASCProject_0097_T3_WES: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Neck; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a676f42a-2442-4b19-b9e7-a113fc4bc285.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0097_SALIVA_2 (Saliva), aliquot ASCProject_0097_SALIVA_2_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d63ed71-f936-4542-bd90-c0f422e19157

The open-access MAF lists 78 somatic variants for this specimen: 47 protein-altering or splice-affecting, 15 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 15, Intron 11, Frame Shift Del 3, Splice Region 2, Splice Site 2, RNA 1, 3'Flank 1, 3'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as rs558155146, COSV51649102; called by muse, mutect2, varscan2
- CENPJ | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.03); catalogued as rs142121392; called by mutect2, varscan2
- CMAS | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1040614577; called by muse, mutect2, varscan2
- CSMD2 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs1436948628, COSV99586366; called by muse, mutect2, varscan2
- CSMD2 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs1330969566, COSV99586370; called by muse, mutect2, varscan2
- DUXA | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as rs371962814; called by muse, mutect2, varscan2
- ELMO2 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.234); catalogued as rs760009580, COSV51682755, COSV51686266; called by muse, mutect2, varscan2
- EML3 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as rs1165597557, COSV53874634; called by muse, mutect2, varscan2
- GYS1 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.174); catalogued as rs1203781149; called by muse, mutect2
- KRT7 | c.693G>A p.T231= | Splice Region (SNP) | VAF 4/38 reads (11%) | catalogued as rs1477121425; called by mutect2, varscan2
- LARP4 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as rs1306719325, COSV99529457; called by mutect2, varscan2
- LMAN2 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.63); catalogued as rs747269398, COSV57426136; called by muse, mutect2, varscan2
- LRRC71 | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100503950; called by muse, mutect2, varscan2
- MAST3 | c.3716G>A p.R1239Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.053); catalogued as rs1033338534; called by muse, mutect2
- MATN3 | c.503C>G p.T168R | Missense Mutation (SNP) | VAF 50/72 reads (69%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as COSV68099761; called by muse, varscan2
- MUC4 | c.15694G>T p.V5232F (on ENST00000463781 / NM_018406.7; = p.V996F on NM_004532.6) | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as rs755720714; called by muse, mutect2, varscan2
- MYO18B | c.7303C>T p.R2435C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs759376174, COSV59145638; called by mutect2, varscan2
- NPIPB15 | c.132C>G p.H44Q | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs763190214, COSV70437206; called by muse, mutect2
- NRCAM | c.2432C>T p.T811M (on ENST00000379028 / NM_001371124.1; = p.T795M on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766439513, COSV100694300; called by muse, mutect2, varscan2
- PARP8 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.549); catalogued as rs775424928; called by mutect2, varscan2
- PLCB4 | c.165+1G>T p.X55_splice | Splice Site (SNP) | VAF 15/124 reads (12%) | catalogued as COSV53793125; called by muse, mutect2, varscan2
- RASAL1 | c.1648G>T p.G550W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV99921594; called by muse, mutect2, varscan2
- TULP4 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV65572617; called by muse, mutect2, varscan2
- USH1G | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746860881; called by muse, mutect2, varscan2
- ZIC5 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1405550387; called by muse, mutect2
- ZNF614 | c.1252C>G p.Q418E | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV54545807; called by muse, mutect2, varscan2
- ZRANB2 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as rs751149078; called by muse, varscan2
- CAMP | c.389A>T p.K130M (on ENST00000296435; = p.K127M on NM_004345.5) | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CEP78 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DENR | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2
- FOXI1 | c.487_488del p.S163Qfs*41 | Frame Shift Del (DEL) | VAF 52/187 reads (28%) | called by pindel, varscan2
- GABRG2 | c.658_659del p.M220Vfs*18 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | called by pindel, varscan2
- GRM4 | c.1689C>A p.D563E | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- HNRNPA0 | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- HSPB8 | c.500A>T p.E167V | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF4B | c.646T>A p.F216I | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEPE | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MYO1F | c.216C>A p.D72E | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NHSL1 | c.676+5_676+8del | Splice Region (DEL) | VAF 23/36 reads (64%) | called by mutect2, pindel, varscan2
- OR52I2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, varscan2
- SEMA4A | c.56del p.F19Sfs*51 | Frame Shift Del (DEL) | VAF 128/596 reads (21%) | called by mutect2, pindel, varscan2
- TXNDC16 | c.243+1G>A p.X81_splice | Splice Site (SNP) | VAF 5/40 reads (13%) | called by mutect2, varscan2
- UNK | c.1699G>A p.G567S | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR72 | c.334dup p.I112Nfs*29 | Frame Shift Ins (INS) | VAF 16/93 reads (17%) | called by mutect2, pindel, varscan2
- ZCCHC3 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF497 | c.821A>C p.H274P | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZSCAN5C | c.1286G>A p.C429Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2
- ABCC3 | c.4131G>A p.S1377= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs974545378; called by muse, mutect2
- BORA | c.1578G>A p.P526= (on ENST00000613797; = p.P451= on NM_024808.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/200 reads (16%) | catalogued as rs554227453; called by muse, mutect2, varscan2
- C19orf54 | c.864G>C p.L288= | Silent (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- CTAGE15 | c.42G>C p.L14= | Silent (SNP) | VAF 24/143 reads (17%) | catalogued as rs747522011; called by muse, mutect2, varscan2
- FMR1NB | c.117G>A p.E39= | Silent (SNP) | VAF 40/72 reads (56%) | called by muse, mutect2, varscan2
- HUNK | c.879C>T p.A293= | Silent (SNP) | VAF 25/46 reads (54%) | called by mutect2, varscan2
- LRSAM1 | c.1152C>T p.D384= | Silent (SNP) | VAF 39/151 reads (26%) | catalogued as rs760074620; ClinVar: likely benign; called by muse, mutect2, varscan2
- NCAPH | c.1803G>A p.Q601= | Silent (SNP) | VAF 86/290 reads (30%) | catalogued as rs377576873, COSV53635997; called by muse, varscan2
- NPAS1 | c.1395G>T p.V465= | Silent (SNP) | VAF 77/553 reads (14%) | called by muse, mutect2, varscan2
- TENM2 | c.2502C>T p.G834= (on ENST00000518659 / NM_001122679.2; = p.G602= on NM_001080428.3) | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs374107882; called by muse, mutect2, varscan2
- TNS2 | c.2487C>A p.G829= (on ENST00000314250 / NM_170754.4; = p.G839= on NM_015319.2) | Silent (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- TRIM51GP | c.441A>G p.L147= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs1162373902; called by muse, mutect2, varscan2
- WDR11 | c.3012A>G p.L1004= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs768066351; called by muse, mutect2, varscan2
- ZNF232 | c.801G>A p.Q267= | Silent (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2
- ZNF865 | c.3096C>G p.L1032= | Silent (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- ARHGAP8 | c.299+278T>C | Intron (SNP) | VAF 6/61 reads (10%) | catalogued as rs1199925933, COSV104396514; called by muse, mutect2
- CEP350 | c.4793-711G>A | Intron (SNP) | VAF 10/108 reads (9%) | catalogued as rs1309866591; called by muse, varscan2
- CNGA1 | c.-15+10490T>G | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as rs1197725004, COSV104422602; called by muse, mutect2
- FAM161A | c.*555T>C | 3'UTR (SNP) | VAF 8/48 reads (17%) | catalogued as rs1195163165; called by mutect2, varscan2
- FBLN5 | c.990-336C>T | Intron (SNP) | VAF 13/79 reads (16%) | catalogued as rs1302973428; called by muse, mutect2, varscan2
- G6PC3 | c.-56T>A | 5'UTR (SNP) | VAF 36/128 reads (28%) | called by mutect2, varscan2
- LINC00303 | n.110C>T | RNA (SNP) | VAF 19/223 reads (9%) | called by muse, mutect2
- MROH7 | c.1231+4994A>G | Intron (SNP) | VAF 8/63 reads (13%) | catalogued as rs1280737551; called by muse, varscan2
- NEK2 | chr1:211658686 T>C | 3'Flank (SNP) | VAF 7/84 reads (8%) | catalogued as rs1327315631; called by muse, varscan2
- NPL | c.231-2879A>G | Intron (SNP) | VAF 8/74 reads (11%) | catalogued as rs1219932377; called by muse, varscan2
- PFKM | c.85+2515G>C | Intron (SNP) | VAF 6/63 reads (10%) | catalogued as rs1436506039; called by mutect2, varscan2
- RN7SL484P | chr15:99790345 C>T | 5'Flank (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- STK32B | c.108+305C>G | Intron (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.2811-22201C>T | Intron (SNP) | VAF 14/116 reads (12%) | catalogued as rs1300835360; called by muse, varscan2
- USP38 | c.1209+891A>T | Intron (SNP) | VAF 5/48 reads (10%) | catalogued as rs752048046; called by mutect2, varscan2
- ZNF141 | c.226+13803A>G | Intron (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
